Surgical pathology report (de-identified scan), TCGA case TCGA-29-1707, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1707-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

[REDACTED]

Surg Path

[REDACTED] CGA-29-1707

CLINICAL HISTORY:

abdominal/pelvic swelling, malignant neoplasm of peritoneum.

GROSS EXAMINATION:

A. "Left tube and ovary (AF1)", received fresh. A 66.8 gram, 5.5 x 5 x 3.2 cm focally disrupted friable mass is received with an overlying 7.5 x 0.5 cm segment of edematous fallopian tube adherent upon its surface. The surface is red-tan with multiple adhesions. Sectioning demonstrates a markedly papillary and friable pink-tan cut surface with an edge of ovarian remnant identified. The interface within the friable mass and the ovarian remnant is distinct. A representative section from the mass is frozen as AF1 and the remnant is submitted as A1. Additional sections to include fallopian tube and ovarian remnant are submitted as blocks A2-6.

B. "Omentum (BF1)", received fresh. A 13 x 10 x 2.5 cm aggregate of finely lobulated yellow-tan adipose consistent with omental tissue is received. No nodules of masses are identified. A representative section is frozen as BF1 and the remnant is submitted as B1. Additional sections are submitted as B2.

C. "Port site", received fresh. A 2.5 x 0.6 cm unoriented ellipse of gray-tan skin excised to a depth of 0.7 cm is inked, sectioned and entirely submitted as C1.

D. "Right tube and ovary", received fresh. A 9.1 gram aggregate of tissue composed of a 4.4 x 0.8 cm segment of fallopian tube and 4.3 x 2.2 x 0.6 cm of adjacent fibrofatty tissue. Representative cross sections from the fallopian tube are submitted as A1. Sectioning through the fibrofatty tissue reveals embedded small staples and vasculature. No ovarian structure is grossly identified. The staples are removed and the remaining fibrofatty tissue is submitted as D1-6 in its entirety.

E. "Uterus and cervix", received fresh. A 164 gram, 12 x 8.5 x 6 cm uterus is received. The ectocervix is tan-white and glistening. The serosa is gray-tan with focal hemorrhagic adhesions. The os is patent and 0.7 cm extending into a trabecular yellow endocervical canal. The endometrium is velvety, tan and 0.2 cm in thickness with a 0.7 cm lower uterine segment/endocervical polyp on the posterior wall (E3). The myometrium is 2.8 cm in thickness with a solitary 3.3 cm firm, white and circumscribed nodule in the right wall. The left wall is expanded by an ill-defined and trabeculated appearance which expands into the wall for 2.7 cm (E6).

BLOCK SUMMARY:

E1- serosal adhesions
E2- anterior cervix
E3- posterior cervix with lower uterine segment polyp
E4- anterior endomyometrium
E5- intramural fibroid
E6- expanded myometrium

F. "Right pelvic sidewall biopsy", received fresh and placed in formalin is a 1.3 x 0.5 x 0.4 cm fragment of fibrofatty tissue which is submitted in toto as F1.

G. "Left pelvic sidewall biopsy", received fresh and placed in formalin. A 1.7 x 0.3 x 0.2 cm yellow-tan fibrous tissue fragment is submitted in toto as G1.

[REDACTED]

[page 2 of 5]
H. "Left IP", received fresh. A 2.4 x 1.7 x 0.6 cm fragment of gray-tan fibrofatty tissue is bisected and entirely submitted as H1.

I. "Sigmoid peritoneum", received fresh. A 2.8 x 2.5 x 1 cm aggregate of red-brown fibrofatty tissue is submitted in toto as I1-2.

J. "Left peroneal sidewall tumor", received fresh. A 3.3 x 1.7 x 0.7 cm fragment of firm gray-tan fibrous tissue is sectioned and entirely submitted as J1-2.

K. "Left pelvic node", received fresh. A 5.4 x 4.4 x 0.6 cm aggregate of fibrofatty tissue containing multiple lymph node candidates is received. The lymph node candidates are submitted as K1 and the remainder of the tissue is submitted as K2-3.

L. "Left obturator", received fresh and placed in formalin. A 3.9 x 2.2 x 1 cm aggregate of fibrofatty tissue is received containing lymph node candidates which are entirely submitted as L1-3.

M. "Left pericolic gutter", received fresh. A 1.5 x 1.4 x 0.3 cm fragment of yellow-tan fibrofatty tissue is submitted in toto as M1.

N. "Right pelvic node", received fresh. An 8.4 x 3.7 x 0.6 cm aggregate of fibrofatty tissue is received containing multiple lymph node candidates and staples.

BLOCK SUMMARY:

N1- lymph node candidate
N2- one bisected lymph node candidate
N3- multiple lymph node candidates
N4- one bisected lymph node candidate

TCGA-29-1707

O. "Presacral", received fresh. A 2.2 x 0.9 x 0.4 cm fragment of fibrofatty tissue is submitted in toto as O1.

P. "Right periaortic", received fresh. A 4.2 x 2.2 x 0.9 cm aggregate of fibrofatty tissue is received containing multiple lymph node candidates. The lymph node candidates are entirely submitted as P1-3.

Q. "Left periaortic", received fresh. A 2.9 x 1.7 x 1.2 cm fragment of fibrofatty tissue is received containing a lymph node candidate which is bisected and entirely submitted as Q1. The remainder of the soft tissue is submitted as Q2.

R. "Left pericolic biopsy", received fresh. A 1.4 x 0.4 x 0.3 cm fragment of yellow-tan fibrofatty tissue is submitted in toto as R1.

INTRA OPERATIVE CONSULTATION:

A. "Left tube and ovary": AFI-poorly differentiated adenocarcinoma

B. "Omentum": BFI-adipose tissue, negative for carcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Hysterectomy, bilateral salpingo-oophorectomy, staging biopsies and node dissections.

PATHOLOGIC STAGE (AJCC 6th Edition): pT3b (see note) pN0 pMX

NOTE: The stage is assigned as pT3b based on the assumption that the specimen labelled "sigmoid peritoneum" (I) is extrapelvic in origin. If this specimen

[page 3 of 5]
is from within the pelvis, the stage would be pT2. Information on pathology stage and the operative procedure is transmitted to this [REDACTED] Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "LEFT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA OF THE OVARY.

FIGO GRADE: 3 OF 3.

TUMOR SIZE: 5.5 X 5 X 3.2 CM.

WEIGHT: 66.8 GRAMS

SEROSA: POSITIVE FOR SURFACE INVOLVEMENT

TCGA-29-1707

FALLOPIAN TUBE: POSITIVE FOR CARCINOMA.

B. "OMENTUM" (OMENTECTOMY):

NEGATIVE FOR CARCINOMA.

C. "PORT SITE" (EXCISION):

SKIN WITH FOREIGN MATERIAL AND SCAR.

NEGATIVE FOR CARCINOMA.

D. "RIGHT TUBE AND OVARY" (RIGHT SALPINGO-OOPHORECTOMY):

FIBROADIPOSE TISSUE AND FALLOPIAN TUBE.

NO OVARIAN TISSUE IS PRESENT.

NEGATIVE FOR MALIGNANCY.

E. "UTERUS AND CERVIX" (HYSTERECTOMY):

UTERUS (164 GRAMS):

SEROSA: POSITIVE FOR IMPLANTED CARCINOMA, WITH LYMPHOVASCULAR INVASION

ENDOMETRIUM: SECRETORY.

MYOMETRIUM: ADENOMYOSIS, AND LEIOMYOMA (3.3 CM).

CERVIX: ENDOCERVICAL POLYP.

F. "RIGHT PELVIC SIDEWALL" (BIOPSY):

NEGATIVE FOR CARCINOMA.

G. "LEFT PELVIC SIDEWALL" (BIOPSY):

NEGATIVE FOR CARCINOMA.

[page 4 of 5]
H. "LEFT IP" (BIOPSY):

NEGATIVE FOR CARCINOMA.

I. "SIGMOID PERITONEUM" (BIOPSY):

POSITIVE FOR CARCINOMA.

TCGA-29-1707

J. "LEFT PERITONEAL SIDEWALL TUMOR" (BIOPSY):

POSITIVE FOR CARCINOMA.

K. "LEFT PELVIC NODE" (DISSECTION):

THREE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/3).

L. "LEFT OBTURATOR" (LYMPH NODE DISSECTION):

THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

M. "LEFT PERICOLIC" (BIOPSY):

NEGATIVE FOR CARCINOMA.

N. "RIGHT PELVIC NODE" (DISSECTION):

NINE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/9).

O. "PRESACRAL" (BIOPSY):

NEGATIVE FOR CARCINOMA.

P. "RIGHT PERIAORTIC" (DISSECTION):

NINE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/9).

Q. "LEFT PARAAORTIC" (DISSECTION):

ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

R. "LEFT PERICOLIC" (BIOPSY):

NEGATIVE FOR CARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[page 5 of 5]
COMMENT:

Several of the lymph nodes have benign lymphangiomyomas.

ADDENDUM 1:

This addendum is issued to report the results of special stains. The previous diagnoses are unchanged.

ADDENDUM DIAGNOSIS:

TCGA-29-1707

Immunoperoxidase stains obtained on a representative section of lymph node with suspected lymphangiomyoma (P3) and show the following results of the tumor cells:

Smooth muscle actin: positive.

HMB-45: positive.

Cytokeratin cocktail (AE3/AE1 CAM 5.2): negative.

These findings support the diagnosis of nodal lymphangiomyomas.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 3f58ac8d-f887-4060-a340-c38e0b678a03 (TCGA-29-1707.DA725324-2B94-47D4-A35C-A5F2233A024F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).